Surgical pathology report (de-identified scan), TCGA case TCGA-96-7544, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - NYU, specimen TCGA-96-7544-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

1. F/S RIGHT LOWER LOBE
2. LEVEL 7 LYMPH NODE

DIAGNOSIS:

1. LUNG, LOWER LOBE, RIGHT: LOBECTOMY

- **INVASIVE SQUAMOUS CELL CARCINOMA, HIGH GRADE (SEE SUMMARY).**
- **METASTATIC SQUAMOUS CELL CARCINOMA IN FOUR OF SEVEN PERIBRONCHIAL AND HILAR LYMPH NODES (4/7).**

2. LYMPH NODES, LEVEL SEVEN: BIOPSY

- **SIX PORTIONS OF LYMPH NODE, NEGATIVE FOR CARCINOMA (0/6).**

MACROSCOPIC SUMMARY: Lung

Specimen Type: Lobectomy

Tumor Site: Right, Lower lobe

Tumor Greatest Dimension: 3.8 cm

MICROSCOPIC SUMMARY:

Histologic Type: Squamous cell carcinoma

Histologic Grade: G3: Poorly differentiated

Extent Of Invasion: T2: Tumor greater than 3 cm in greatest dimension

Margins: Uninvolved by invasive carcinoma

Blood/Lymphatic Vessel Invasion: Absent/not observed

Venous Invasion: Absent/not observed

Regional Lymph Nodes: N1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, including intrapulmonary nodes involved by direct extension of the primary tumor

Nodes Examined: 13

Nodes Involved: 4

Distant Metastasis: MX: Cannot be assessed

Direct Extension Of Tumor: Stage Grouping: Not applicable

Additional Pathologic Findings: Squamous metaplasia; meningotheial-like nodule; patchy interstitial fibrosis and peribronchiolar metaplasia

Pathologist

[page 2 of 3]
CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

Right lower lobe mass.

MACROSCOPIC DESCRIPTION:

The specimen is received in two parts each labeled with the patient's name.

1. Part one is received fresh labeled 'right lower lobe'. It consists of a 20 x 13 x 4.5 cm, 259 gram, lobectomy specimen. There is a 1.2 x 1 cm bronchial margin and a 1 x 0.3 cm stapled vessel margin. Sectioning at the hilum reveals multiple red-black, soft lymph nodes measuring 0.3 to 0.5 cm in diameter. The pleural surface is red and smooth and is inked in black. Cut section reveals a well-circumscribed, firm, white-gray, lobulated tumor measuring 3.8 x 2 x 2 cm, located 0.4 cm from the overlying pleura and 0.7 cm from the bronchial margin. The tumor abuts the nearby bronchioles. The surrounding lung parenchyma shows anthracotic pigmentation. No other lesions or masses are identified. Representative sections are submitted in thirteen cassettes.

2. Part two is received in formalin labeled 'level 7 lymph node'. It consists of multiple, soft, red-black possible lymph nodes measuring 0.4 x 0.4 x 0.3 cm to 1 x 0.7 x 0.5 cm. Entirely submitted in two cassettes.

SUMMARY OF SECTIONS:

1A portion of tumor for frozen section
1B,1C bronchial and vessel margins
1D hilar lymph nodes
1E-1G tumor to pleura
1H tumor, representative
1I,1J tumor to nearby bronchiole
1K-1M normal lung
2A multiple lymph nodes
2B multiple lymph nodes

INTRA - OPERATIVE CONSULTATION:

1. Lung, right lower lobe: Resection (frozen section and touch preparation)
- Invasive squamous cell carcinoma.

[page 3 of 3]
Results reported by Dr. [REDACTED]
back by Dr. [REDACTED]

Intra-Operative Consultation #1 performed by

[REDACTED]

Final Diagnosis performed by

[REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED]

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 398a59db-5eb2-4699-b2a7-76f4d2299772 (TCGA-96-7544.32BAED4B-24E5-4B74-86B7-21A15E48E1DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).